Somatic mutation profile of tumor specimen C3N-00646-03 (aliquot CPT0081990006) from CPTAC case C3N-00646, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.9 years (21,144 days).
Specimen C3N-00646-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10faa943-9e12-45a8-92ea-48477701d6cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00646-71 (Blood Derived Normal), aliquot CPT0082030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e382a746-dc71-4b9d-9127-7d7a81972c71

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 12 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 12, Frame Shift Del 6, Intron 4, Nonsense Mutation 4, 3'UTR 3, Splice Region 3, 5'UTR 2, 3'Flank 2, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHEB | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 28/176 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519950, COSV51262364, COSV51263550; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs796051897; called by muse, mutect2
- ACTL7B | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480803021; called by muse, mutect2, varscan2
- ATAD2 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.098); catalogued as COSV54881193; called by muse, mutect2
- DDX50 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104424183; called by muse, mutect2
- ELAVL4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1345370346, COSV63914597; called by muse, mutect2
- GRIN3A | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62453111; called by muse, mutect2, varscan2
- HS3ST2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 28/334 reads (8%) | catalogued as rs1336994762, COSV54457839; called by muse, mutect2
- MCCD1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs773573995, COSV66018785; called by muse, mutect2
- PAM | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 44/459 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57216591; called by muse, mutect2
- PASD1 | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 44/451 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1306096843; called by muse, mutect2
- RFX6 | c.1715C>A p.S572* | Nonsense Mutation (SNP) | VAF 73/627 reads (12%) | catalogued as COSV60585069; called by muse, mutect2, varscan2
- SLC38A1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV67064301; called by muse, mutect2
- TFE3 | c.114C>A p.L38= | Splice Region (SNP) | VAF 12/86 reads (14%) | catalogued as COSV59946412; called by muse, varscan2
- TFIP11 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV53226609; called by muse, mutect2, varscan2
- USP38 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761444526; called by muse, mutect2
- VANGL2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759727082; called by muse, mutect2
- ZP3 | c.1183G>T p.A395S (on ENST00000394857 / NM_001110354.2; = p.A344S on NM_007155.6) | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as COSV100334553; called by muse, varscan2
- ABCA1 | c.5935T>G p.S1979A | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ARHGEF19 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.376); called by muse, mutect2
- ASTN1 | c.1075del p.L359* | Frame Shift Del (DEL) | VAF 26/185 reads (14%) | called by mutect2, pindel, varscan2
- C12orf40 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CALB2 | c.628-2A>T p.X210_splice | Splice Site (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- CCDC57 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CDCA2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CLMN | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CSTF2T | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 27/313 reads (9%) | called by muse, mutect2
- CYP2A6 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ENPEP | c.1021T>G p.Y341D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EVI5 | c.1549A>G p.R517G | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBRS | c.722del p.P241Lfs*63 (on ENST00000287468; = p.P761Lfs*63 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 40/228 reads (18%) | called by mutect2, pindel, varscan2
- GGA3 | c.801del p.S267Rfs*43 (on ENST00000537686 / NM_138619.4; = p.S234Rfs*43 on NM_014001.5) | Frame Shift Del (DEL) | VAF 40/258 reads (16%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.9581T>C p.I3194T | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GULP1 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2
- KIAA0100 | c.2530G>C p.V844L | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- LIPC | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 71/591 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LYPD3 | c.382+4C>A | Splice Region (SNP) | VAF 78/573 reads (14%) | called by muse, mutect2, varscan2
- MAPK15 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.359); called by muse, mutect2
- MED13 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MLLT3 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- MPV17L2 | c.223T>A p.F75I | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MTHFD1L | c.1056del p.K352Nfs*52 | Frame Shift Del (DEL) | VAF 35/192 reads (18%) | called by mutect2, pindel, varscan2
- MUC17 | c.10990_10994del p.T3664Cfs*15 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel
- MYH7B | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); called by muse, mutect2
- OTOA | c.2187C>G p.D729E (on ENST00000286149; = p.D715E on NM_144672.4) | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PCDHB6 | c.1348A>C p.T450P | Missense Mutation (SNP) | VAF 98/978 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PDAP1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- PRELP | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RALGAPA2 | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS14 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RXRA | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 65/561 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR2 | c.11177A>G p.Y3726C | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SACS | c.8626G>A p.E2876K | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SDCCAG8 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC1A5 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 50/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A14 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- SPEM1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2
- SPINK4 | c.216-5C>T | Splice Region (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2, varscan2
- TAF7L | c.1321_1324delinsAAAA p.Q441_E442delinsKK | Missense Mutation (ONP) | VAF 5/39 reads (13%) | called by muse*, pindel
- TEDC1 | c.574dup p.L192Pfs*19 | Frame Shift Ins (INS) | VAF 10/122 reads (8%) | called by mutect2, pindel
- TRIP12 | c.5224G>T p.D1742Y | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC3 | c.5646T>G p.S1882R | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- UTP23 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR35 | c.414del p.V139* | Frame Shift Del (DEL) | VAF 39/316 reads (12%) | called by mutect2, pindel, varscan2
- ZBTB11 | c.3050T>A p.M1017K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF750 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF91 | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ZSCAN29 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FBN2 | c.3798C>T p.C1266= | Silent (SNP) | VAF 80/624 reads (13%) | called by muse, mutect2, varscan2
- FUT5 | c.147T>A p.L49= | Silent (SNP) | VAF 50/585 reads (9%) | called by muse, mutect2
- FZD9 | c.1248C>T p.F416= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as COSV60669665; called by muse, mutect2, varscan2
- HDAC7 | c.351G>T p.L117= (on ENST00000427332; = p.L156= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- ITGB1BP1 | c.294T>C p.D98= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs201976301, COSV99432091; called by muse, mutect2, varscan2
- MANBA | c.1986A>G p.K662= (on ENST00000642252; = p.K616= on NM_005908.4) | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as CD065752; called by muse, mutect2, varscan2
- MED13 | c.2292T>C p.R764= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- MUC6 | c.4662C>A p.T1554= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs755302968, COSV70143201; called by muse, mutect2
- PCDHA3 | c.84C>T p.S28= | Silent (SNP) | VAF 36/269 reads (13%) | catalogued as COSV65367526, COSV65368417; called by muse, mutect2, varscan2
- PLEK | c.427C>T p.L143= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99029643; called by muse, mutect2
- SNX25 | c.1617T>C p.V539= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs1248221421; called by muse, mutect2, varscan2
- THEM4 | c.75G>A p.P25= | Silent (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- AC009053.1 | chr16:74336615 C>T | 3'Flank (SNP) | VAF 28/544 reads (5%) | called by muse, mutect2
- AQP3 | c.-42C>A | 5'UTR (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2
- CC2D1B | c.*386_*391del | 3'UTR (DEL) | VAF 20/136 reads (15%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.*202C>T | 3'UTR (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- CEACAM21 | c.-4G>A | 5'UTR (SNP) | VAF 18/179 reads (10%) | catalogued as rs1489304664; called by muse, mutect2, varscan2
- CELP | chr9:133086294 C>G | 3'Flank (SNP) | VAF 43/338 reads (13%) | called by muse, mutect2, varscan2
- DCAF17 | c.*602T>C | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- DLGAP4 | c.1648+15587_1648+15588del | Intron (DEL) | VAF 30/269 reads (11%) | called by mutect2, pindel
- FAM205BP | n.923G>T | RNA (SNP) | VAF 51/672 reads (8%) | called by muse, mutect2
- FBRS | chr16:30662466 A>G | 5'Flank (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- METTL15 | c.779-2272C>T | Intron (SNP) | VAF 7/67 reads (10%) | catalogued as rs768331835; called by muse, mutect2, varscan2
- SPG7 | c.1642+1113del | Intron (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel, varscan2
- TIA1 | c.310+30A>G | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
